Somatic mutation profile of tumor specimen MP2PRT-PAUKTI-TMP1-A (aliquot MP2PRT-PAUKTI-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUKTI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,754 days).
Specimen MP2PRT-PAUKTI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00c3e2f7-8872-478c-865c-48a07adba00d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKTI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKTI-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f9baddb-e85c-47ac-a585-bdfae9bb5ec8

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Nonsense Mutation 5, 3'Flank 2, Intron 1, In Frame Ins 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 79/272 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADD2 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274559163, COSV52457725; called by muse, mutect2
- ADRA2A | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 50/750 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762180589, COSV99701615; called by muse, mutect2
- ATM | c.6490G>C p.E2164Q | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1317619286, COSV53730905, COSV53774759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP4 | c.1052C>G p.S351* | Nonsense Mutation (SNP) | VAF 23/636 reads (4%) | catalogued as COSV55415496; called by muse, mutect2
- BRCA2 | c.9679C>G p.Q3227E | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1408001886, COSV66337799; ClinVar: uncertain significance; called by muse, mutect2
- CCAR1 | c.2590G>C p.D864H | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV56271082; called by muse, mutect2
- CNKSR2 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 106/551 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99667122; called by muse, mutect2, varscan2
- CNN2 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 26/681 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1233615567; called by muse, mutect2
- CTDP1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 152/691 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV50003192; called by muse, mutect2, varscan2
- ELF4 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 21/823 reads (3%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.679); catalogued as COSV57451241, COSV57454554; called by muse, mutect2
- FAT1 | c.7360C>T p.R2454W | Missense Mutation (SNP) | VAF 48/536 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs202097333, COSV101499375; called by muse, mutect2
- HDGFL3 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1275477672; called by muse, mutect2, varscan2
- HERC2 | c.10639C>T p.R3547C | Missense Mutation (SNP) | VAF 164/758 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs559745379, COSV55318427; called by muse, mutect2, varscan2
- HK3 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 101/467 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs757213611; called by muse, mutect2, varscan2
- KAZN | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs545673997; called by muse, mutect2
- KCNH8 | c.3309A>C p.K1103N | Missense Mutation (SNP) | VAF 25/369 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.116); catalogued as COSV100110631; called by muse, mutect2
- KCNK15 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 55/689 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs550127808; called by muse, mutect2
- KCNN2 | c.1676G>A p.R559Q (on ENST00000264773; = p.R771Q on NM_021614.4) | Missense Mutation (SNP) | VAF 85/452 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as rs774628560, COSV99300464; called by muse, mutect2, varscan2
- KRT39 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 25/605 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62917075; called by muse, mutect2
- LINGO2 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV100430741, COSV58056887; called by muse, mutect2
- LPA | c.3840G>C p.Q1280H | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs1322500917; called by muse, mutect2
- MUC16 | c.23177C>T p.A7726V | Missense Mutation (SNP) | VAF 48/493 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1437444610, COSV67461987; called by muse, mutect2
- NCKAP5L | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 45/612 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373189569; called by muse, mutect2
- OR5B17 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV100641837, COSV100641907; called by muse, mutect2, varscan2
- PCDHGB1 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 135/664 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs781780297; called by muse, mutect2, varscan2
- PKHD1L1 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 13/343 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65737629, COSV65747244; called by muse, mutect2
- SLC8A1 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV60480499; called by muse, mutect2
- WDFY3 | c.5489C>T p.S1830F | Missense Mutation (SNP) | VAF 144/409 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs3098927; called by muse, mutect2, varscan2
- ZNF737 | c.1014G>C p.E338D | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs782656519; called by muse, mutect2, varscan2
- ADAMTS12 | c.3059A>C p.K1020T | Missense Mutation (SNP) | VAF 99/498 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCNB2 | c.554A>G p.E185G | Missense Mutation (SNP) | VAF 186/413 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP1 | c.1950G>C p.K650N | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- FNTB | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2B | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); called by muse, mutect2
- HECTD1 | c.6919A>C p.T2307P | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406870 del ATTCACAGTGTT | Missense Mutation (DEL) | VAF 78/135 reads (58%) | called by mutect2, varscan2
- INSM1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 29/804 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- LATS1 | c.1827G>C p.Q609H | Missense Mutation (SNP) | VAF 12/444 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- LRP1B | c.1516G>C p.G506R | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEBL | c.1647G>C p.K549N | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- NNT | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2
- OR2L2 | c.152A>C p.D51A | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- P2RY1 | c.1020G>C p.R340S | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2
- P4HB | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 12/346 reads (3%) | called by muse, mutect2
- PNLIPRP2 | c.461T>A p.L154Q | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLR3GL | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.315); called by muse, mutect2
- QPCTL | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 76/362 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3845G>C p.G1282A | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAPGEF6 | c.4087G>A p.G1363R | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RPLP0 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 17/490 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- SHANK3 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 89/582 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SLC8A3 | c.1682C>T p.T561I | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TANC2 | c.3156G>C p.L1052F | Missense Mutation (SNP) | VAF 103/462 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TLE4 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 16/340 reads (5%) | called by muse, mutect2
- WNT3A | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 85/691 reads (12%) | called by muse, mutect2, varscan2
- ZMYM2 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 117/295 reads (40%) | called by muse, mutect2, varscan2
- ZNF486 | c.1097_1098insCCCCCT p.T366_M367insPL | In Frame Ins (INS) | VAF 162/390 reads (42%) | called by mutect2, varscan2*
- ADAD1 | c.1701A>G p.K567= | Silent (SNP) | VAF 43/305 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.1890C>T p.S630= | Silent (SNP) | VAF 41/427 reads (10%) | called by muse, mutect2
- ARNT2 | c.399C>T p.L133= | Silent (SNP) | VAF 18/333 reads (5%) | catalogued as rs753824772; called by muse, mutect2
- EFCAB9 | c.570C>G p.L190= | Silent (SNP) | VAF 13/243 reads (5%) | called by muse, mutect2
- FERMT3 | c.804G>A p.L268= | Silent (SNP) | VAF 51/403 reads (13%) | called by muse, mutect2, varscan2
- FNDC1 | c.1044G>A p.T348= | Silent (SNP) | VAF 69/381 reads (18%) | catalogued as rs761535434, COSV99794587; called by muse, mutect2, varscan2
- GNL1 | c.1282C>T p.L428= | Silent (SNP) | VAF 90/439 reads (21%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.348C>A p.T116= | Silent (SNP) | VAF 77/141 reads (55%) | called by mutect2, varscan2
- MTCL1 | c.5646G>A p.S1882= (on ENST00000306329 / NM_001378206.1; = p.S1563= on NM_015210.4) | Silent (SNP) | VAF 186/390 reads (48%) | catalogued as rs377258454; called by muse, mutect2, varscan2
- NCKAP5L | c.513C>A p.A171= | Silent (SNP) | VAF 134/581 reads (23%) | catalogued as COSV60127292; called by muse, mutect2, varscan2
- PCNX3 | c.5781C>G p.L1927= | Silent (SNP) | VAF 38/909 reads (4%) | catalogued as COSV100856185; called by muse, mutect2
- PRRC2C | c.8328G>A p.L2776= (on ENST00000367742; = p.L2774= on NM_015172.4) | Silent (SNP) | VAF 123/573 reads (21%) | called by muse, mutect2, varscan2
- PRSS23 | c.795G>C p.V265= | Silent (SNP) | VAF 86/521 reads (17%) | called by muse, mutect2, varscan2
- RANBP2 | c.6522G>A p.K2174= | Silent (SNP) | VAF 41/501 reads (8%) | called by muse, mutect2, varscan2
- SALL3 | c.432G>T p.A144= | Silent (SNP) | VAF 194/907 reads (21%) | called by muse, mutect2, varscan2
- SLC19A2 | c.36G>A p.A12= | Silent (SNP) | VAF 42/777 reads (5%) | called by muse, mutect2
- SLC2A6 | c.492C>T p.G164= | Silent (SNP) | VAF 18/610 reads (3%) | catalogued as rs782184798, COSV64143073; called by muse, mutect2
- TAF1 | c.2913A>C p.T971= (on ENST00000373790 / NM_138923.4; = p.T992= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 167/410 reads (41%) | called by muse, mutect2, varscan2
- WDR87 | c.3732C>T p.D1244= | Silent (SNP) | VAF 71/423 reads (17%) | catalogued as rs544768229; called by muse, mutect2, varscan2
- DEUP1 | c.30-2940C>G | Intron (SNP) | VAF 41/253 reads (16%) | called by muse, mutect2, varscan2
- ROR2 | chr9:91722567 C>T | 3'Flank (SNP) | VAF 75/422 reads (18%) | catalogued as rs762549385; called by muse, mutect2, varscan2
- SATL1 | c.-340G>T | 5'UTR (SNP) | VAF 127/584 reads (22%) | called by muse, mutect2, varscan2
- TRAJ52 | chr14:22490490 ins AGGGTA | 3'Flank (INS) | VAF 50/126 reads (40%) | called by mutect2, varscan2
